Somatic mutation profile of tumor specimen TARGET-30-PANPVI-01A (aliquot TARGET-30-PANPVI-01A-01W) from TARGET case TARGET-30-PANPVI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.5 years (1,289 days).
Specimen TARGET-30-PANPVI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fac25844-fd05-4a0a-99b6-9078cdf16583.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANPVI-14A (Bone Marrow Normal), aliquot TARGET-30-PANPVI-14A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e1a8211-a897-4ceb-afa8-2c91b3480cb5

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.4651C>A p.L1551M | Missense Mutation (SNP) | VAF 99/724 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as rs765882044, COSV60629186; called by muse, mutect2, varscan2
- C1orf112 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53681603, COSV99609668; called by muse, mutect2, varscan2
- DDX60 | c.3245G>T p.S1082I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV67098412; called by muse, mutect2, varscan2
- FLG2 | c.4824G>T p.E1608D | Missense Mutation (SNP) | VAF 229/991 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV66171561; called by muse, mutect2, varscan2
- FREM2 | c.4350C>A p.N1450K | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV54847081; called by muse, mutect2, varscan2
- MRI1 | c.657G>T p.E219D (on ENST00000040663 / NM_001031727.4; = p.E172D on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.101); catalogued as COSV50005148; called by muse, mutect2, varscan2
- NUP98 | c.2558A>T p.E853V | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100263741, COSV61436698; called by muse, mutect2, varscan2
- OR2L3 | c.575G>T p.W192L | Missense Mutation (SNP) | VAF 158/824 reads (19%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.597); catalogued as COSV63455955; called by muse, varscan2
- PTPRT | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 55/480 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs756719404, COSV61991055; called by mutect2, varscan2
- RGL4 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.483); catalogued as COSV51945022; called by muse, mutect2, varscan2
- SI | c.4937C>A p.T1646N | Missense Mutation (SNP) | VAF 77/424 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV52293323; called by muse, mutect2, varscan2
- ZNF785 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs1279551150, COSV67876515; called by muse, mutect2, varscan2
- DNAH17 | c.2735_2736del p.F912* | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by pindel, varscan2
- PIK3C2G | c.3989A>T p.N1330I (on ENST00000676171; = p.N1289I on NM_004570.5) | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- YEATS2 | c.2080A>G p.T694A | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.031); called by muse, mutect2
- CEP95 | c.1275C>T p.I425= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as rs782628612, COSV73609541; called by muse, mutect2, varscan2
- SRRM1 | c.2115G>A p.S705= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs764762086, COSV60479670; called by muse, mutect2, varscan2
- STRIP2 | c.282C>A p.G94= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV50807097; called by muse, mutect2, varscan2
